Somatic mutation profile of tumor specimen 42216d99-e8ff-43c9-b6db-28c3a6 (aliquot 42216d99-e8ff-43c9-b6db-28c3a6_D6) from CPTAC case 05CO034, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB.
Specimen 42216d99-e8ff-43c9-b6db-28c3a6: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2185dbb8-cc52-4e90-b171-572e91992042.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen e2ef6cb4-e7d6-45e1-ac92-947fb5 (Blood Derived Normal), aliquot e2ef6cb4-e7d6-45e1-ac92-947fb5_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2952e3ac-debd-4adc-932c-622129663ab2

The open-access MAF lists 102 somatic variants for this specimen: 66 protein-altering or splice-affecting, 28 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 28, Nonsense Mutation 6, Intron 4, Splice Site 1, Frame Shift Del 1, 3'UTR 1, 5'Flank 1, Splice Region 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 52/172 reads (30%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 185/373 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- LOXHD1 | c.4843G>A p.G1615R | Missense Mutation (SNP) | VAF 91/223 reads (41%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.926); catalogued as rs768835732, COSV100191564; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SATB2 | c.1696G>A p.E566K | Missense Mutation (SNP) | VAF 136/329 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.602); catalogued as rs1064795530, COSV53477421; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 100/176 reads (57%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADCK5 | c.1226A>C p.D409A | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.381); catalogued as rs782208902, COSV58233174; called by muse, mutect2, varscan2
- BRINP2 | c.2242C>T p.R748W | Missense Mutation (SNP) | VAF 76/178 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs1452978190, COSV64177810; called by muse, mutect2, varscan2
- CCDC105 | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 52/171 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1363224809, COSV52963869; called by muse, mutect2, varscan2
- CCDC185 | c.1112G>A p.R371Q | Missense Mutation (SNP) | VAF 65/181 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.02); catalogued as rs557959151, COSV64821620; called by muse, mutect2, varscan2
- CD163 | c.485C>T p.T162M | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1350984804; called by muse, mutect2, varscan2
- CSMD3 | c.6563C>T p.S2188F (on ENST00000297405 / NM_001363185.1; = p.S2084F on NM_052900.3) | Missense Mutation (SNP) | VAF 107/291 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as COSV52108195; called by muse, mutect2, varscan2
- CTNNB1 | c.1955-1G>A p.X652_splice | Splice Site (SNP) | VAF 210/403 reads (52%) | catalogued as COSV62691011; called by muse, mutect2, varscan2
- DNAJC13 | c.3659C>T p.A1220V | Missense Mutation (SNP) | VAF 39/199 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs575026402, COSV53449599; called by muse, mutect2, varscan2
- ELFN2 | c.100G>A p.V34M | Missense Mutation (SNP) | VAF 107/236 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs989247282; called by muse, mutect2, varscan2
- FUT10 | c.308A>G p.D103G | Missense Mutation (SNP) | VAF 58/116 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as rs200145592; called by muse, mutect2, varscan2
- GTF3C1 | c.253T>A p.L85M | Missense Mutation (SNP) | VAF 31/219 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.549); catalogued as COSV55191477; called by muse, mutect2, varscan2
- HAPLN4 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 67/257 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.041); catalogued as COSV52270292; called by muse, mutect2, varscan2
- IKZF1 | c.1543C>T p.R515C | Missense Mutation (SNP) | VAF 111/244 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1270036178, COSV58785900; called by muse, mutect2, varscan2
- ITGB4 | c.1164G>T p.K388N | Missense Mutation (SNP) | VAF 52/236 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.079); catalogued as COSV52327305; called by mutect2, varscan2
- KALRN | c.3826C>T p.R1276W | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1038128039, COSV53758304; called by muse, mutect2, varscan2
- MDGA2 | c.1349G>C p.R450T (on ENST00000399232 / NM_001113498.2; = p.R152T on NM_182830.4) | Missense Mutation (SNP) | VAF 117/248 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.913); catalogued as COSV100636730, COSV62077705; called by muse, varscan2
- N4BP2 | c.824T>C p.V275A | Missense Mutation (SNP) | VAF 51/174 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1488006517; called by muse, mutect2, varscan2
- NCKAP5 | c.2927G>T p.G976V | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.916); catalogued as COSV58474570; called by muse, mutect2, varscan2
- NUMA1 | c.5146C>T p.P1716S | Missense Mutation (SNP) | VAF 160/329 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV59643519; called by muse, mutect2, varscan2
- PBX3 | c.1102G>A p.G368R | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV60731162; called by muse, mutect2, varscan2
- PTCD2 | c.506A>G p.N169S | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.289); catalogued as rs1259241589; called by muse, mutect2, varscan2
- PTPRM | c.2519A>G p.Y840C | Missense Mutation (SNP) | VAF 33/178 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); catalogued as rs142726956; called by muse, mutect2, varscan2
- R3HDM4 | c.724C>T p.R242W | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs202187618; called by muse, mutect2, varscan2
- RAI14 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as rs201315302; called by muse, mutect2, varscan2
- SDK1 | c.5089G>A p.G1697S | Missense Mutation (SNP) | VAF 15/161 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as rs745306432, COSV67373695; called by muse, mutect2
- SLIT3 | c.3463G>A p.E1155K | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as rs775301864; called by muse, mutect2, varscan2
- SLITRK1 | c.364C>T p.R122* | Nonsense Mutation (SNP) | VAF 42/805 reads (5%) | catalogued as COSV65674345, COSV65674425; called by muse, mutect2
- SMC4 | c.2271A>C p.K757N | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.312); catalogued as COSV61004119; called by muse, mutect2, varscan2
- THEG | c.638C>T p.T213M | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs574618110; called by muse, mutect2, varscan2
- TMEM94 | c.1396C>T p.R466* | Nonsense Mutation (SNP) | VAF 55/225 reads (24%) | catalogued as rs777469062, COSV58594989, COSV58601566; called by muse, mutect2, varscan2
- TPTE | c.1138G>A p.E380K (on ENST00000618007 / NM_199261.4; = p.E362K on NM_199259.4) | Missense Mutation (SNP) | VAF 24/254 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs781489069; called by muse, mutect2
- TSPAN10 | c.233C>A p.A78E (on ENST00000574882 / NM_001290212.1; = p.A40E on NM_031945.4) | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.423); catalogued as rs770610273; called by muse, mutect2, varscan2
- ZNF425 | c.1426G>A p.G476S | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as COSV100955639; called by muse, mutect2, varscan2
- ZNF839 | c.2413C>T p.R805C (on ENST00000558850 / NM_001267827.1; = p.R921C on NM_018335.5) | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); catalogued as rs573029148, COSV99216264; called by muse, mutect2, varscan2
- APC | c.1665del p.D556Mfs*2 | Frame Shift Del (DEL) | VAF 40/157 reads (25%) | called by mutect2, pindel, varscan2
- C16orf96 | c.5G>A p.S2N | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- C4orf17 | c.530T>G p.L177R | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CCDC168 | c.6576G>A p.M2192I | Missense Mutation (SNP) | VAF 181/510 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CEP290 | c.5149A>G p.R1717G | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CGNL1 | c.3638G>C p.R1213P | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CLMP | c.608C>G p.S203C | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- EPPIN | c.168C>A p.D56E | Missense Mutation (SNP) | VAF 109/415 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- FAT3 | c.5642C>T p.P1881L | Missense Mutation (SNP) | VAF 130/281 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRHL2 | c.166G>A p.G56S | Missense Mutation (SNP) | VAF 65/200 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRXCR1 | c.714G>T p.E238D | Missense Mutation (SNP) | VAF 66/229 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- HUWE1 | c.784C>T p.R262* | Nonsense Mutation (SNP) | VAF 29/211 reads (14%) | called by muse, mutect2, varscan2
- INTS8 | c.2433T>G p.F811L | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- LRP1B | c.8380C>A p.L2794I | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- NBEA | c.2578G>A p.E860K | Missense Mutation (SNP) | VAF 63/158 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- NRG3 | c.1391G>T p.S464I | Missense Mutation (SNP) | VAF 100/213 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- NUTM1 | c.1655G>C p.R552T | Missense Mutation (SNP) | VAF 40/180 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- OR51V1 | c.142G>T p.V48F | Missense Mutation (SNP) | VAF 77/137 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- PEX5L | c.747T>G p.H249Q | Missense Mutation (SNP) | VAF 10/149 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PLPPR4 | c.658G>T p.V220L | Missense Mutation (SNP) | VAF 33/179 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PLPPR5 | c.706C>A p.L236I | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by mutect2, varscan2
- PLSCR5 | c.371C>A p.T124K | Missense Mutation (SNP) | VAF 36/212 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- RMND5B | c.829G>C p.G277R | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SLC13A5 | c.1275+5C>G | Splice Region (SNP) | VAF 50/97 reads (52%) | called by muse, mutect2, varscan2
- SLFN12L | c.562A>C p.T188P (on ENST00000260908 / NM_001363830.1; = p.T206P on NM_001195790.1) | Missense Mutation (SNP) | VAF 69/156 reads (44%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- WAS | c.133A>G p.T45A | Missense Mutation (SNP) | VAF 65/316 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.156); called by mutect2, varscan2
- ZNF471 | c.1603A>T p.K535* | Nonsense Mutation (SNP) | VAF 70/235 reads (30%) | called by muse, mutect2, varscan2
- ADGRB1 | c.3216C>G p.T1072= | Silent (SNP) | VAF 27/66 reads (41%) | called by muse, mutect2, varscan2
- ADGRL4 | c.1078C>A p.R360= | Silent (SNP) | VAF 31/69 reads (45%) | catalogued as COSV66060741; called by muse, mutect2, varscan2
- ADHFE1 | c.34T>C p.L12= | Silent (SNP) | VAF 19/53 reads (36%) | called by muse, mutect2, varscan2
- APOA2 | c.177C>T p.A59= | Silent (SNP) | VAF 142/362 reads (39%) | catalogued as rs370208442; called by muse, mutect2, varscan2
- C6orf118 | c.903G>A p.T301= | Silent (SNP) | VAF 14/129 reads (11%) | catalogued as rs760308731; called by muse, mutect2
- CD1B | c.333C>T p.P111= | Silent (SNP) | VAF 10/85 reads (12%) | catalogued as COSV63804314; called by muse, mutect2, varscan2
- CDH23 | c.7848C>T p.N2616= | Silent (SNP) | VAF 129/331 reads (39%) | catalogued as rs951916941, COSV56474741; called by muse, mutect2, varscan2
- CDH6 | c.1056T>A p.P352= | Silent (SNP) | VAF 38/112 reads (34%) | called by muse, mutect2, varscan2
- DMRT1 | c.183G>A p.S61= | Silent (SNP) | VAF 32/118 reads (27%) | called by muse, mutect2, varscan2
- EEF1AKMT1 | c.462G>A p.S154= | Silent (SNP) | VAF 165/447 reads (37%) | catalogued as rs142311304; called by muse, mutect2, varscan2
- EVX2 | c.786C>T p.T262= | Silent (SNP) | VAF 22/168 reads (13%) | catalogued as rs1026491399; called by muse, mutect2, varscan2
- FAM25C | c.37C>T p.L13= | Silent (SNP) | VAF 13/204 reads (6%) | called by muse, mutect2
- FAM25G | c.37C>T p.L13= | Silent (SNP) | VAF 24/182 reads (13%) | called by muse, mutect2, varscan2
- FAM47A | c.207C>T p.L69= | Silent (SNP) | VAF 24/258 reads (9%) | catalogued as rs1268699735, COSV60493988; called by muse, mutect2
- GAS7 | c.603C>T p.C201= (on ENST00000432992 / NM_201433.2; = p.C61= on NM_003644.3) | Silent (SNP) | VAF 27/94 reads (29%) | catalogued as rs1238163107, COSV60435467; called by muse, mutect2, varscan2
- GPR180 | c.1146C>T p.S382= | Silent (SNP) | VAF 45/121 reads (37%) | catalogued as rs1407805518; called by muse, mutect2, varscan2
- HSPB8 | c.9C>T p.D3= | Silent (SNP) | VAF 66/372 reads (18%) | catalogued as rs952834680; called by muse, mutect2, varscan2
- KLHL30 | c.198C>T p.F66= | Silent (SNP) | VAF 92/251 reads (37%) | catalogued as rs748354076, COSV59977118; called by muse, mutect2, varscan2
- LAMB2 | c.1083C>A p.A361= | Silent (SNP) | VAF 169/345 reads (49%) | called by muse, mutect2, varscan2
- MTO1 | c.1941G>A p.V647= (on ENST00000370300 / NM_133645.3; = p.V622= on NM_012123.4) | Silent (SNP) | VAF 17/120 reads (14%) | called by muse, mutect2, varscan2
- NCAM1 | c.1803C>T p.S601= (on ENST00000316851 / NM_181351.5; = p.S591= on NM_000615.7) | Silent (SNP) | VAF 93/183 reads (51%) | catalogued as rs536431053, COSV57516384; called by muse, mutect2, varscan2
- NTNG2 | c.354G>A p.P118= | Silent (SNP) | VAF 96/239 reads (40%) | catalogued as rs1292519021, COSV62365507, COSV62365925; called by muse, mutect2, varscan2
- RNF114 | c.189C>T p.V63= | Silent (SNP) | VAF 34/172 reads (20%) | called by muse, mutect2, varscan2
- SIGLEC14 | c.378A>G p.V126= | Silent (SNP) | VAF 56/482 reads (12%) | called by muse, mutect2, varscan2
- SLC45A1 | c.1464C>T p.N488= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as rs368396525; called by muse, varscan2
- TGM7 | c.1749C>T p.R583= | Silent (SNP) | VAF 43/186 reads (23%) | catalogued as rs745467206, COSV71772632; called by muse, mutect2, varscan2
- UNC5B | c.1578C>T p.S526= | Silent (SNP) | VAF 59/281 reads (21%) | catalogued as rs775350591, COSV58979039; called by muse, mutect2, varscan2
- ZNF138 | c.879C>T p.T293= (on ENST00000307355 / NM_001367572.1; = p.T267= on NM_006524.4) | Silent (SNP) | VAF 35/190 reads (18%) | called by muse, mutect2, varscan2
- C1orf159 | c.-22-9C>T | Intron (SNP) | VAF 37/213 reads (17%) | catalogued as rs1259055272; called by muse, mutect2, varscan2
- FLRT2 | chr14:85529073 C>T | 5'Flank (SNP) | VAF 52/120 reads (43%) | called by muse, mutect2, varscan2
- FRMD8P1 | n.346G>T | RNA (SNP) | VAF 161/748 reads (22%) | called by muse, mutect2, varscan2
- MAP4K4 | c.2220+723G>A | Intron (SNP) | VAF 33/139 reads (24%) | catalogued as rs780225062; called by muse, mutect2, varscan2
- SH3TC2 | c.*963C>T | 3'UTR (SNP) | VAF 11/59 reads (19%) | called by muse, mutect2
- SLC14A1 | c.-22+2282C>T | Intron (SNP) | VAF 106/262 reads (40%) | called by muse, varscan2
- TPM3 | c.244-6890C>T | Intron (SNP) | VAF 67/330 reads (20%) | catalogued as rs201126385; called by muse, mutect2, varscan2
- ZNF254 | c.-80C>T | 5'UTR (SNP) | VAF 24/106 reads (23%) | called by muse, mutect2, varscan2
